CCDI case PBCFKA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/a6c2db2c-1e44-4359-bb9d-d7d05cb1e731

Demographics
Sex at birth: female.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 8.7 years (3,181 days).

Biospecimens (3 samples)
- Sample 0DQU4D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQU51: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQU5C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
